Surgical pathology report (de-identified scan), TCGA case TCGA-61-1900, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1900-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY -

- A. PAPILLARY SEROUS ADENOCARCINOMA OF OVARY, HIGH-GRADE, 11 CM IN GREATEST DIMENSION, WITH SURFACE EXTENSION.
- B. NO LYMPHOVASCULAR INVASION SEEN.
- C. FALLOPIAN TUBE WITH ATYPICAL HYPERPLASIA OF A TUBAL EPITHELIUM.
- D. PARATUBAL CYST AND ADIPOSE TISSUE ADHERENT TO FIMBRIATED END.

PART 2: UTERUS (198 g) AND LEFT ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND LEFT SALPINGO-OOPHORECTOMY -

- A. OVARY WITH SURFACE IMPLANTS OF PAPILLARY SEROUS ADENOCARCINOMA, HIGH GRADE.
- B. DISORDERED PROLIFERATIVE ENDOMETRIUM.
- C. ADENOMYOSIS.
- D. LEIOMYOMATA, UP TO 1.3 CM IN DIAMETER.
- E. FALLOPIAN TUBE WITH ATYPICAL HYPERPLASIA OF TUBAL EPITHELIUM.
- F. PARATUBAL CYST.
- G. CERVIX WITH CHRONIC INFLAMMATION AND SQUAMOUS METAPLASIA.

PART 3: OMENTUM, OMENTECTOMY -

INVASIVE SEROUS ADENOCARCINOMA IN OMENTAL ADIPOSE TISSUE.

PART 4: APPENDIX, APPENDECTOMY -

UNREMARKABLE APPENDIX.

PART 5: LEFT PELVIC LYMPH NODES, BIOPSIES -

FIVE LYMPH NODES NEGATIVE FOR METASTATIC TUMOR (0/5).

PART 6: RIGHT PELVIC LYMPH NODES, BIOPSIES -

TWO LYMPH NODES NEGATIVE FOR METASTATIC TUMOR (0/2).

PART 7: LEFT PERIAORTIC LYMPH NODES, BIOPSIES -

TWO LYMPH NODES NEGATIVE FOR METASTATIC TUMOR (0/2).

PART 8: RIGHT PERIAORTIC LYMPH NODES, BIOPSIES -

THREE LYMPH NODES NEGATIVE FOR METASTATIC TUMOR (0/3).

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 11 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Papillary (2)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
VASCULAR INVASION:	No
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Omentum
ASSOCIATED OTHER LESION:	Other lesion(s) Atypical epithelial hyperplasia of the fallopian tube
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 12
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 0 Number of positive lymph nodes, Left: 0
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIB

Source: NCI Genomic Data Commons file 1288c586-e329-46bc-83f9-eee5f19be111 (TCGA-61-1900.B0DD202D-16DC-42EC-AD83-6F02B37B919F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).